Somatic mutation profile of tumor specimen C3L-09552-04 (aliquot CPT0515800008) from CPTAC case C3L-09552, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 46.3 years (16,900 days).
Specimen C3L-09552-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d759c14-3a3c-4b77-afdf-6c8952b85654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09552-31 (Blood Derived Normal), aliquot CPT0515920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d744303-0e86-4c08-abdb-8a3dfcb1dbcb

The open-access MAF lists 639 somatic variants for this specimen: 454 protein-altering or splice-affecting, 154 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 358, Silent 154, Frame Shift Del 51, Intron 15, Nonsense Mutation 14, Frame Shift Ins 14, In Frame Del 9, 3'UTR 7, 5'UTR 4, Splice Region 3, Splice Site 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 94/770 reads (12%) | hotspot (GDC flag); catalogued as rs587780784, CM022775, COSV55727261; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 84/958 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs749718096, COSV100239902, COSV57482702; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 102/857 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 218/1716 reads (13%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA2 | c.4015G>A p.G1339R (on ENST00000614293; = p.G1309R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/886 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344219972; called by muse, mutect2, varscan2
- ABCB1 | c.3043del p.T1015Pfs*3 | Frame Shift Del (DEL) | VAF 151/1267 reads (12%) | catalogued as COSV55964223; called by mutect2, pindel, varscan2
- ABCB6 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 62/594 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs772193917, COSV54693396; called by muse, varscan2
- ABCC1 | c.4528G>A p.A1510T | Missense Mutation (SNP) | VAF 142/1236 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs764004869, COSV60682736; called by muse, varscan2
- ACOT8 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 73/722 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs748247124; called by muse, mutect2, varscan2
- ACOX3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 127/1259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs145226987, COSV62711159; called by muse, mutect2, varscan2
- ACSM4 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 115/1071 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372795810; called by muse, varscan2
- ACTR8 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV51638085; called by muse, mutect2, varscan2
- ADAMTS17 | c.2212G>T p.G738C | Missense Mutation (SNP) | VAF 70/1678 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51474717; called by muse, mutect2
- ADCY6 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 89/693 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs773191127; called by muse, mutect2, varscan2
- ADD2 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 194/1674 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.129); catalogued as rs114311724; called by muse, mutect2, varscan2
- AKAP1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 102/1834 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.829); catalogued as COSV58468693; called by muse, mutect2
- AKAP3 | c.1877G>T p.R626M | Missense Mutation (SNP) | VAF 96/935 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV57414413; called by muse, mutect2, varscan2
- ALAD | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 116/724 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs371983646; called by muse, mutect2, varscan2
- ANGPT4 | c.904A>G p.S302G | Missense Mutation (SNP) | VAF 161/1197 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1218810897; called by muse, mutect2, varscan2
- ANKRD60 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 212/1510 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs141764287, COSV64518255; called by muse, mutect2, varscan2
- ANO2 | c.2675C>T p.S892L (on ENST00000356134 / NM_001278597.3; = p.S896L on NM_001278596.3) | Missense Mutation (SNP) | VAF 146/1107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767967144, COSV59020201, COSV59035280; called by muse, mutect2, varscan2
- AP3B2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 102/654 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99916738; called by muse, mutect2, varscan2
- APOBEC3D | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 91/809 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs1235067428; called by muse, mutect2, varscan2
- ARHGEF17 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 221/1655 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1038055507; called by muse, varscan2
- ARID1A | c.1015del p.A339Lfs*24 | Frame Shift Del (DEL) | VAF 221/1870 reads (12%) | catalogued as rs1232964733; called by mutect2, pindel, varscan2
- ARID1B | c.3157G>T p.E1053* | Nonsense Mutation (SNP) | VAF 268/1054 reads (25%) | catalogued as rs1554231195, COSV51648627, COSV51664268; called by muse, mutect2, varscan2
- ASAP3 | c.1344C>A p.D448E | Missense Mutation (SNP) | VAF 151/1145 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as rs1432211584; called by muse, mutect2, varscan2
- ATF6 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 82/691 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs768955438; called by muse, mutect2, varscan2
- ATP10A | c.1814C>T p.T605M | Missense Mutation (SNP) | VAF 85/675 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs777490269, COSV63518958; called by muse, mutect2, varscan2
- ATXN7L1 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 147/1470 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs375510569; called by muse, mutect2
- B3GALT4 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 174/1316 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV65851218; called by muse, mutect2, varscan2
- BANP | c.1301C>A p.P434H (on ENST00000286122; = p.P406H on NM_079837.3) | Missense Mutation (SNP) | VAF 110/804 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as COSV53744893; called by muse, mutect2, varscan2
- BAP1 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 163/1223 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs779877855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEND6 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 104/1011 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV66069898; called by muse, mutect2, varscan2
- BRAT1 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 179/1455 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs770105500; called by muse, mutect2, varscan2
- BRD4 | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 110/947 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1234699192, COSV54585613; called by muse, mutect2, varscan2
- BSN | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 186/1356 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1283198454, COSV56519123; called by muse, varscan2
- C16orf71 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 163/1177 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs774575818, COSV73918480; called by muse, mutect2, varscan2
- C8A | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 80/819 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.288); catalogued as rs758167128; called by muse, mutect2
- CACNA1B | c.5228G>A p.R1743H | Missense Mutation (SNP) | VAF 76/719 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1231982669; called by muse, mutect2, varscan2
- CACNA1C | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 82/604 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59747910, COSV59785774; called by muse, mutect2, varscan2
- CACNA1H | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 135/963 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs1266233731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CC2D1A | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 170/1126 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs753360853, COSV58785071; called by muse, mutect2, varscan2
- CCDC114 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 216/1664 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs746996781; called by muse, mutect2, varscan2
- CCDC40 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 169/1197 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs367783575; called by muse, mutect2, varscan2
- CCNB2 | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 96/770 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1403060049; called by muse, mutect2, varscan2
- CCNJL | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 193/1537 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs187903121; called by muse, mutect2, varscan2
- CDH23 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 180/1688 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758293939; called by muse, mutect2, varscan2
- CDH9 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 60/536 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751593635, COSV50256584; called by muse, mutect2, varscan2
- CDKN1A | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 164/944 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576307617; called by muse, mutect2, varscan2
- CFAP43 | c.791_793del p.T264del | In Frame Del (DEL) | VAF 12/136 reads (9%) | catalogued as rs1342825665; called by pindel, varscan2
- CHSY3 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 239/1602 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100520019; called by muse, mutect2, varscan2
- CILP | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 205/1413 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs376689702; called by muse, mutect2, varscan2
- COBL | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 210/2013 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs376448766; called by muse, mutect2, varscan2
- COBL | c.2344C>T p.R782* | Nonsense Mutation (SNP) | VAF 134/1307 reads (10%) | catalogued as COSV54340240; called by muse, mutect2, varscan2
- COL17A1 | c.3592G>A p.V1198M | Missense Mutation (SNP) | VAF 118/939 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs755782951; called by muse, varscan2
- CORIN | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 93/782 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs200249247, COSV56685848, COSV99902736; called by muse, mutect2, varscan2
- CPEB3 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 222/1660 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs775961940; called by mutect2, varscan2
- CPSF1 | c.4138G>A p.A1380T | Missense Mutation (SNP) | VAF 121/970 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1304420700; called by muse, mutect2, varscan2
- CYP4F11 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 101/818 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201156268, COSV56125672; called by muse, mutect2, varscan2
- DCAF8L1 | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 32/618 reads (5%) | catalogued as COSV101491567; called by muse, mutect2
- DCHS2 | c.1976A>G p.N659S | Missense Mutation (SNP) | VAF 51/1312 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1372402510; called by muse, mutect2
- DCLK3 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 134/1174 reads (11%) | catalogued as rs745309900, COSV69363405; called by muse, varscan2
- DGKG | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 143/1238 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs531767196; called by muse, mutect2, varscan2
- DHX57 | c.3995G>A p.R1332H | Missense Mutation (SNP) | VAF 106/862 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as rs764774893; called by muse, varscan2
- DMTN | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 63/568 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1158821092; called by muse, mutect2, varscan2
- DNAH8 | c.11720G>A p.R3907Q | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.292); catalogued as rs371307226; called by muse, mutect2, varscan2
- DND1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 132/1143 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs902189822; called by muse, varscan2
- DOC2B | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1274430339; called by muse, mutect2, varscan2
- DOCK6 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 140/1120 reads (13%) | catalogued as rs774140725; called by muse, varscan2
- DRD2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 197/1654 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748462272, COSV60754096; called by muse, mutect2, varscan2
- DSTYK | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 79/821 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs775610801; called by muse, mutect2
- DYRK1A | c.952-1G>A p.X318_splice | Splice Site (SNP) | VAF 32/251 reads (13%) | catalogued as COSV58292538; called by muse, mutect2, varscan2
- EFR3B | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 101/1176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs993618185, COSV67837806; called by muse, mutect2
- EHD4 | c.1579dup p.H527Pfs*58 | Frame Shift Ins (INS) | VAF 134/1016 reads (13%) | catalogued as rs758354312; called by mutect2, varscan2
- ENC1 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 130/1149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369287784; called by muse, varscan2
- EPPK1 | c.4607C>T p.A1536V | Missense Mutation (SNP) | VAF 138/1261 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs782364262, COSV73262432, COSV73262441; called by muse, varscan2
- ERAP2 | c.693T>G p.I231M | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs1364047890; called by muse, mutect2
- ERGIC3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 154/1172 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs751656462; called by muse, mutect2, varscan2
- EVI5 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 162/1340 reads (12%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs142905346; called by muse, mutect2, varscan2
- FAM149A | c.1513C>T p.H505Y (on ENST00000356371 / NM_001367768.2; = p.H214Y on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 235/1687 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs774929109; called by muse, mutect2, varscan2
- FAT1 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 90/875 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs750719535, COSV71675513; called by muse, mutect2, varscan2
- FBXL7 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 158/1371 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.816); catalogued as rs768251957, COSV61642031; called by muse, mutect2, varscan2
- FBXW5 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 192/1354 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs771667923, COSV56402422; called by muse, mutect2, varscan2
- FCRL2 | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 118/923 reads (13%) | catalogued as COSV100829912, COSV63833300; called by mutect2, varscan2
- FER1L5 | c.4882C>T p.R1628W (on ENST00000623019; = p.R1601W on NM_001293083.2) | Missense Mutation (SNP) | VAF 134/974 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760818257; called by muse, mutect2, varscan2
- FHOD3 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 108/949 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as rs186410723, COSV99942225; called by muse, mutect2, varscan2
- FLAD1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 134/1174 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs201824694; called by muse, mutect2, varscan2
- FLG | c.10351G>A p.E3451K | Missense Mutation (SNP) | VAF 194/1649 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as rs370743517, COSV64252662; called by muse, mutect2, varscan2
- FLNC | c.4445T>C p.L1482P | Missense Mutation (SNP) | VAF 125/1004 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.393); catalogued as COSV100367562; called by muse, mutect2, varscan2
- FREM3 | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 118/1035 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs1283289306; called by muse, mutect2, varscan2
- GAS6 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 328/1152 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1429779557; called by muse, varscan2
- GATA2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 161/1184 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs1269493584; called by muse, mutect2, varscan2
- GATA5 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 124/1199 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs139687383; called by muse, mutect2, varscan2
- GFRA2 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 131/990 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs771727278, COSV60778545; called by muse, varscan2
- GGT5 | c.474del p.W159Gfs*51 | Frame Shift Del (DEL) | VAF 222/1746 reads (13%) | catalogued as COSV54071213; called by mutect2, pindel, varscan2
- GNAS | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 279/2016 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as rs1473713580; called by muse, mutect2, varscan2
- GOLT1A | c.221del p.G74Vfs*64 | Frame Shift Del (DEL) | VAF 137/1132 reads (12%) | catalogued as rs765260894; called by mutect2, pindel, varscan2
- GOT2 | c.296T>C p.I99T | Missense Mutation (SNP) | VAF 92/1025 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs982114598; called by muse, mutect2
- GPT2 | c.1035C>T p.G345= | Splice Region (SNP) | VAF 91/813 reads (11%) | catalogued as rs778652804; called by muse, mutect2, varscan2
- GSE1 | c.3220G>A p.A1074T | Missense Mutation (SNP) | VAF 176/1538 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.236); catalogued as rs376390313, COSV53670926; called by muse, mutect2, varscan2
- GSTO2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 93/786 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1297791574; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1731C>T p.Y577= | Splice Region (SNP) | VAF 132/1365 reads (10%) | catalogued as rs587665093; called by muse, mutect2
- HDAC4 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 134/1095 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs371367857; called by muse, mutect2, varscan2
- HDGFL2 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 157/1167 reads (13%) | SIFT tolerated, low confidence (1); catalogued as rs1049343594; called by muse, mutect2, varscan2
- IFT140 | c.1545_1547del p.L516del | In Frame Del (DEL) | VAF 34/238 reads (14%) | catalogued as rs1210664549; called by pindel, varscan2
- IGF2 | c.577C>T p.R193C (on ENST00000434045 / NM_001127598.3; = p.R137C on NM_000612.6) | Missense Mutation (SNP) | VAF 198/2013 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1338558695; called by muse, mutect2, varscan2
- IL21R | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 109/953 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61969489; called by muse, mutect2, varscan2
- IL4R | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 185/1520 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs749041212, COSV50160433; called by muse, varscan2
- IRAG1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 183/1456 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs747215099; called by muse, mutect2, varscan2
- IRS2 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 214/2008 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.92); catalogued as COSV65481522; called by muse, mutect2, varscan2
- JAG1 | c.3343G>A p.V1115M | Missense Mutation (SNP) | VAF 145/1296 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as rs148373907; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- JCAD | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 167/1541 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs200411233, COSV64760632; called by muse, mutect2, varscan2
- KIF15 | c.2837C>T p.T946M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767689315, COSV58159673; called by muse, mutect2, varscan2
- KIF26A | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 191/1552 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs774212043; called by muse, mutect2, varscan2
- KLF13 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 166/1211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775602171; called by muse, mutect2, varscan2
- KMT2B | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 246/2013 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as rs369788045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L3MBTL4 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 43/432 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1241340509; called by muse, mutect2, varscan2
- LARP4B | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 86/1001 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1564399291, COSV60222789; called by muse, mutect2
- LIPH | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs146753303; called by muse, mutect2, varscan2
- LMO7 | c.896del p.L299Yfs*15 (on ENST00000357063; = p.L314Yfs*15 on NM_005358.5) | Frame Shift Del (DEL) | VAF 189/720 reads (26%) | catalogued as COSV58534028; called by mutect2, pindel, varscan2
- LRFN1 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 166/1143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV50440564; called by muse, mutect2, varscan2
- LRRN4CL | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 229/1688 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs551756407, COSV99628566; called by muse, mutect2, varscan2
- LRSAM1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 146/1077 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs772786050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRWD1 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 128/979 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1280853788; called by mutect2, varscan2
- MAP3K9 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 156/1239 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1291849494; called by muse, mutect2, varscan2
- MARK2 | c.1667C>T p.P556L (on ENST00000402010 / NM_001039469.2; = p.P522L on NM_017490.4) | Missense Mutation (SNP) | VAF 138/1026 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.125); catalogued as rs781744203; called by muse, mutect2, varscan2
- MAST4 | c.4096G>A p.G1366R (on ENST00000403625 / NM_001164664.2; = p.G1177R on NM_015183.3) | Missense Mutation (SNP) | VAF 211/1514 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368420355; called by muse, mutect2, varscan2
- MFSD1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs753535023, COSV51843367; called by muse, varscan2
- MKS1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 160/1190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768171144, COSV56597015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MST1 | c.1288_1290del p.E430del | In Frame Del (DEL) | VAF 164/1020 reads (16%) | catalogued as rs751306787; called by pindel, varscan2
- MYH7 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 143/1288 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs749007293, COSV100806431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 123/947 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772577695, COSV99338031; called by muse, mutect2, varscan2
- MYO15A | c.7243C>T p.R2415C | Missense Mutation (SNP) | VAF 134/1136 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1016332945; called by muse, mutect2, varscan2
- MYOM2 | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 197/1368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771411219, COSV50758155; called by muse, mutect2, varscan2
- NKX2-8 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 166/1309 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1459833649, COSV99352550; called by muse, mutect2, varscan2
- NMNAT2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 156/1263 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs762590558, COSV54268434; called by muse, mutect2, varscan2
- NODAL | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 180/1287 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99755413; called by muse, mutect2, varscan2
- NPAS3 | c.944C>T p.A315V (on ENST00000356141 / NM_001164749.2; = p.A283V on NM_022123.3) | Missense Mutation (SNP) | VAF 145/1311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV60822417; called by muse, mutect2, varscan2
- NPTX2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 280/1761 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV99675182; called by muse, mutect2, varscan2
- NQO2 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 198/837 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57642685; called by mutect2, varscan2
- NRP1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 142/992 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1376849398; called by muse, mutect2, varscan2
- NRP2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 206/1531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746710925; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 190/1287 reads (15%) | catalogued as rs753966040; called by pindel, varscan2
- OR10AC1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 195/1566 reads (12%) | SIFT tolerated, low confidence (0.08); catalogued as rs1401797274; called by muse, mutect2, varscan2
- OR52E8 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 136/1268 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770223346, COSV66205845; called by muse, varscan2
- OR5D13 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 68/670 reads (10%) | catalogued as rs753203578, COSV62334553; called by muse, varscan2
- OR6N1 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 107/930 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58647870; called by muse, mutect2, varscan2
- OTUD7A | c.1751C>T p.A584V (on ENST00000307050 / NM_001382637.1; = p.A577V on NM_130901.3) | Missense Mutation (SNP) | VAF 224/1718 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100191793; called by muse, mutect2, varscan2
- P4HB | c.550T>A p.F184I | Missense Mutation (SNP) | VAF 159/1026 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58941945; called by muse, mutect2, varscan2
- PCDHB7 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 333/2740 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.458); catalogued as rs148889209; called by muse, mutect2, varscan2
- PCDHGA3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 184/1961 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV53905106; called by muse, mutect2
- PCDHGB1 | c.1856C>T p.T619M | Missense Mutation (SNP) | VAF 110/1142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54005003; called by muse, mutect2, varscan2
- PCED1A | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 52/1324 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1472922878, COSV62314156; called by muse, mutect2
- PCLO | c.12600G>A p.M4200I | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61634163; called by muse, mutect2
- PCLO | c.8750C>T p.S2917L | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs868319700; called by muse, mutect2
- PCNT | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 111/866 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1188351667; called by muse, mutect2, varscan2
- PDIA2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 244/1617 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753974693; called by muse, mutect2, varscan2
- PDZD4 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 247/935 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51248243; called by muse, mutect2, varscan2
- PER2 | c.3163G>A p.G1055S | Missense Mutation (SNP) | VAF 181/1509 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs1402470714, COSV54523522; called by muse, mutect2, varscan2
- PIK3C2A | c.3095G>A p.G1032D | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1334520637; called by muse, mutect2
- PISD | c.407G>A p.R136H (on ENST00000439502 / NM_001326412.1; = p.R102H on NM_014338.3) | Missense Mutation (SNP) | VAF 178/1384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768687189, COSV99837473; called by muse, mutect2, varscan2
- PKHD1 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 120/992 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs138620202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB3 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 179/1348 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.56); catalogued as rs780232749, COSV54186687; called by muse, mutect2, varscan2
- PLCD3 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 101/709 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs200234852; called by muse, mutect2, varscan2
- PLD3 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 84/691 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs145888304; called by muse, mutect2, varscan2
- PLOD2 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 145/920 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs754523284; called by muse, mutect2, varscan2
- PLXNA1 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 148/1375 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs747504201; called by muse, mutect2, varscan2
- PLXNA1 | c.3826C>T p.R1276C | Missense Mutation (SNP) | VAF 154/1111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1000962009; called by muse, mutect2, varscan2
- PNPLA1 | c.121del p.R41Gfs*17 | Frame Shift Del (DEL) | VAF 278/2144 reads (13%) | catalogued as rs1414059926; called by mutect2, pindel, varscan2
- PNPLA5 | c.318dup p.D107Rfs*19 | Frame Shift Ins (INS) | VAF 210/1590 reads (13%) | catalogued as rs747771692; called by mutect2, pindel, varscan2
- POLR3G | c.413C>T p.T138M (on ENST00000399107; = p.D128= on NM_006467.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as rs138635696; called by muse, mutect2
- POLR3H | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 123/859 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs766381344, COSV53443498; called by muse, mutect2, varscan2
- POP1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 146/1008 reads (14%) | catalogued as rs199760739; called by muse, varscan2
- POTEB3 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 100/1840 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs1400384731; called by muse, mutect2
- PRRT4 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 133/1159 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs375091041, COSV71054258; called by muse, mutect2, varscan2
- PVRIG | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 207/1487 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV52781007; called by muse, mutect2, varscan2
- QRICH2 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 118/944 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148545764; called by muse, mutect2, varscan2
- RAB40C | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 204/1501 reads (14%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs145997805; called by muse, varscan2
- RAD23A | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 144/1230 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs148187629; called by muse, mutect2, varscan2
- RAD54L2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 154/1213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559647350, COSV56576751; called by muse, mutect2, varscan2
- RASGRP3 | c.369T>A p.I123= | Splice Region (SNP) | VAF 23/229 reads (10%) | catalogued as COSV67825471; called by muse, mutect2
- RBM20 | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 197/1487 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs375798246, CM107459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOG | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 164/1277 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99544425; called by muse, mutect2, varscan2
- RNF123 | c.3248G>A p.R1083H | Missense Mutation (SNP) | VAF 93/839 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1337238409, COSV57538887; called by muse, varscan2
- RNF207 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 127/884 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100933723; called by muse, varscan2
- RNF214 | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 67/395 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV100326506; called by muse, mutect2, varscan2
- RRBP1 | c.2482C>T p.R828W (on ENST00000377813 / NM_001365613.2; = p.R395W on NM_004587.3) | Missense Mutation (SNP) | VAF 115/1013 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261503459; called by muse, mutect2, varscan2
- S1PR5 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 238/1502 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.054); catalogued as rs1568405986, COSV61014018; called by muse, mutect2, varscan2
- SAFB | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 56/662 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52651644; called by muse, mutect2
- SAMD14 | c.1141C>T p.R381C (on ENST00000330175 / NM_001257359.2; = p.R409C on NM_174920.4) | Missense Mutation (SNP) | VAF 154/1346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs147639995; called by muse, mutect2, varscan2
- SBF1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 153/1015 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs768921617, COSV62367437; called by muse, mutect2, varscan2
- SBNO2 | c.3647G>T p.R1216L | Missense Mutation (SNP) | VAF 185/1205 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as rs1395017443; called by muse, mutect2, varscan2
- SCFD2 | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 60/580 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs562363082; called by muse, mutect2
- SCN4A | c.5337G>A p.M1779I | Missense Mutation (SNP) | VAF 197/1372 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV101438706; called by muse, mutect2, varscan2
- SCUBE2 | c.2616del p.K873Sfs*5 (on ENST00000649792 / NM_001367977.2; = p.K816Sfs*5 on NM_020974.3) | Frame Shift Del (DEL) | VAF 205/1783 reads (11%) | catalogued as rs753114269; called by mutect2, pindel, varscan2
- SDC1 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 210/1804 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1006285002; called by muse, mutect2, varscan2
- SEMA4A | c.2270G>A p.G757D | Missense Mutation (SNP) | VAF 100/840 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV61773583; called by muse, mutect2, varscan2
- SERPINE1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 81/752 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.297); catalogued as rs748847141, COSV56169013; called by muse, mutect2, varscan2
- SGSM3 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 179/1387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1217578636; called by muse, mutect2, varscan2
- SH3PXD2A | c.871G>A p.V291I (on ENST00000369774 / NM_001365079.1; = p.V263I on NM_014631.2) | Missense Mutation (SNP) | VAF 125/1176 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs751502344; called by muse, mutect2, varscan2
- SLA | c.166G>T p.G56W (on ENST00000338087 / NM_001045556.3; = p.G96W on NM_006748.4) | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55071062, COSV55078454; called by muse, mutect2
- SLC1A3 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 103/918 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs746980992; called by muse, mutect2, varscan2
- SLC7A14 | c.1354_1356del p.K452del | In Frame Del (DEL) | VAF 98/856 reads (11%) | catalogued as rs768771659; called by pindel, varscan2
- SLC9A1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 164/1344 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs1364813844; called by muse, mutect2, varscan2
- SMAP2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 76/710 reads (11%) | catalogued as rs1167856207, COSV65533919; called by muse, mutect2, varscan2
- SMCHD1 | c.175T>C p.C59R | Missense Mutation (SNP) | VAF 150/946 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV55262775; called by muse, mutect2, varscan2
- SNX18 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 224/1228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1311904479, COSV100410370, COSV100410461; called by muse, mutect2, varscan2
- SOST | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 131/1064 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs867579353; called by muse, varscan2
- SOX10 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 236/1685 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119676, CM119679, COSV62806811; called by muse, mutect2, varscan2
- STK16 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 197/1197 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764004179, COSV99850189; called by muse, mutect2, varscan2
- STYX | c.296dup p.M101Yfs*3 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | catalogued as rs769509399; called by pindel, varscan2
- TAF11L12 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 102/1100 reads (9%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs535482374; called by muse, mutect2
- TAF3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 49/1186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1198170174; called by muse, mutect2
- TBRG4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 191/1433 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs145556572; called by muse, mutect2, varscan2
- TBXA2R | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 200/1523 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs376762511; called by muse, mutect2, varscan2
- TCIRG1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 97/815 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229911430; called by muse, mutect2, varscan2
- TEDC1 | c.910C>T p.R304C (on ENST00000392523 / NM_001367178.1; = p.R235C on NM_001134875.1) | Missense Mutation (SNP) | VAF 198/1317 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1454359879; called by muse, mutect2, varscan2
- TFDP2 | c.1045A>G p.I349V (on ENST00000489671 / NM_001178139.2; = p.I289V on NM_006286.5) | Missense Mutation (SNP) | VAF 53/445 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs907569504, COSV57705830; called by muse, mutect2, varscan2
- THBS1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 164/1308 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.467); catalogued as rs370731208; called by muse, varscan2
- THBS1 | c.206del p.P69Lfs*26 | Frame Shift Del (DEL) | VAF 181/1567 reads (12%) | catalogued as COSV52949806; called by mutect2, pindel, varscan2
- THUMPD2 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 51/586 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760928207, COSV53186788; called by muse, mutect2
- TMC6 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 137/874 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1406614435, COSV59209131; called by muse, mutect2, varscan2
- TMEM235 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 109/1060 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1305149755; called by muse, mutect2, varscan2
- TMEM30B | c.273del p.C92Afs*23 | Frame Shift Del (DEL) | VAF 147/1214 reads (12%) | catalogued as rs979697561; called by mutect2, pindel, varscan2
- TNFAIP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 122/991 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50228132; called by muse, mutect2, varscan2
- TNS2 | c.1613G>A p.R538Q (on ENST00000314250 / NM_170754.4; = p.R548Q on NM_015319.2) | Missense Mutation (SNP) | VAF 301/1882 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs757424331, COSV100048892; called by muse, mutect2, varscan2
- TOR4A | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 54/1370 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs779627310; called by muse, mutect2
- TRAPPC9 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 176/1266 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.28); catalogued as COSV104430845; called by muse, mutect2, varscan2
- TRPM4 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 136/1207 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs764385592, COSV99420741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPV4 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 107/992 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs780568107; called by muse, mutect2, varscan2
- TSPOAP1 | c.3043C>T p.R1015W | Missense Mutation (SNP) | VAF 126/1133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375143610; called by muse, mutect2, varscan2
- TTLL3 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 106/911 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373790516; called by muse, mutect2, varscan2
- TYK2 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 163/1389 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs764267766; called by muse, mutect2, varscan2
- UBR4 | c.5725C>T p.R1909C | Missense Mutation (SNP) | VAF 162/1126 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs1306164698, COSV100920348; called by muse, mutect2, varscan2
- UNG | c.640G>A p.A214T (on ENST00000242576 / NM_080911.3; = p.A205T on NM_003362.4) | Missense Mutation (SNP) | VAF 88/920 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.228); catalogued as rs1375530817, COSV54359030; called by muse, mutect2
- UNKL | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 151/1162 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs145589979; called by muse, mutect2, varscan2
- USP19 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 203/1423 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs771925404; called by muse, mutect2, varscan2
- VASH1 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 184/1441 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1419984167, COSV51335171; called by muse, mutect2, varscan2
- VSTM4 | c.322dup p.A108Gfs*53 (on ENST00000332853 / NM_001031746.5; = p.A108Gfs*87 on NM_144984.4) | Frame Shift Ins (INS) | VAF 163/1465 reads (11%) | catalogued as rs781660756; called by mutect2, pindel, varscan2
- WDR38 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 178/1056 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs766705959, COSV62161207; called by muse, mutect2, varscan2
- WHAMM | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 107/880 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs757526203; called by muse, mutect2, varscan2
- XIRP2 | c.6673G>T p.E2225* (on ENST00000628543; = p.E2400* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 104/1167 reads (9%) | catalogued as COSV54681248; called by muse, mutect2
- ZBTB7C | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 176/1261 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as rs776047154; called by muse, mutect2, varscan2
- ZNF195 | c.1704_1705del p.H568Qfs*13 (on ENST00000399602 / NM_001130520.3; = p.H496Qfs*13 on NM_007152.5) | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | catalogued as rs1246898904; called by mutect2, varscan2
- ZNF236 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 82/670 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53482531, COSV53484482; called by muse, varscan2
- ZNF454 | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60769234; called by muse, mutect2
- ZNF473 | c.143del p.P48Qfs*5 | Frame Shift Del (DEL) | VAF 104/843 reads (12%) | catalogued as rs1568408902; called by mutect2, pindel, varscan2
- ZNF479 | c.381del p.K127Nfs*74 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs782331095; called by mutect2, pindel, varscan2
- ZNF507 | c.999_1001del p.S336del | In Frame Del (DEL) | VAF 62/570 reads (11%) | catalogued as rs1386100519; called by pindel, varscan2
- ZNF599 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 100/903 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs767574920, COSV61395883; called by muse, mutect2, varscan2
- ZNF628 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 173/1271 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs780998618; called by muse, mutect2, varscan2
- ZSWIM1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 113/820 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140182403; called by muse, mutect2, varscan2
- ABCC12 | c.1255del p.S419Afs*18 | Frame Shift Del (DEL) | VAF 33/339 reads (10%) | called by mutect2, pindel
- ACE | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 135/1218 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTR1B | c.490del p.V164Sfs*155 | Frame Shift Del (DEL) | VAF 116/1010 reads (11%) | called by mutect2, pindel, varscan2
- ALCAM | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- AMDHD2 | c.-12_2del | Translation Start Site (DEL) | VAF 143/1089 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.3749dup p.L1250Ffs*11 | Frame Shift Ins (INS) | VAF 95/751 reads (13%) | called by mutect2, pindel, varscan2
- APBA1 | c.963del p.Q322Sfs*39 | Frame Shift Del (DEL) | VAF 195/1507 reads (13%) | called by mutect2, pindel, varscan2
- APEH | c.2113del p.S705Afs*16 | Frame Shift Del (DEL) | VAF 66/530 reads (12%) | called by pindel, varscan2
- ARID1A | c.400del p.A134Rfs*98 | Frame Shift Del (DEL) | VAF 130/1067 reads (12%) | called by mutect2, pindel, varscan2
- ARPP21 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 52/460 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASH2L | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 131/1131 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATP8B2 | c.1054G>A p.A352T (on ENST00000672630; = p.A319T on NM_001005855.2) | Missense Mutation (SNP) | VAF 148/1295 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ATRNL1 | c.248C>A p.P83Q | Missense Mutation (SNP) | VAF 181/1445 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIK | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 121/774 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- BRD1 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 99/738 reads (13%) | called by muse, mutect2, varscan2
- C11orf95 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 190/1525 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- C17orf80 | c.1562del p.P521Lfs*11 | Frame Shift Del (DEL) | VAF 81/645 reads (13%) | called by mutect2, pindel, varscan2
- CAPN5 | c.1112G>A p.C371Y (on ENST00000456580; = p.C331Y on NM_004055.5) | Missense Mutation (SNP) | VAF 75/719 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CARD10 | c.1582G>T p.A528S | Missense Mutation (SNP) | VAF 148/1014 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.339); called by mutect2, varscan2
- CARNS1 | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 61/500 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC149 | c.1538G>A p.S513N (on ENST00000635206 / NM_001330643.2; = p.S502N on NM_173463.5) | Missense Mutation (SNP) | VAF 172/1196 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.444); called by muse, varscan2
- CCDC88A | c.4540G>C p.V1514L (on ENST00000436346 / NM_001365480.1; = p.V1486L on NM_018084.5) | Missense Mutation (SNP) | VAF 91/632 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CCT8L2 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 83/1266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CD248 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 50/1489 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- CDC23 | c.421dup p.L141Pfs*9 | Frame Shift Ins (INS) | VAF 25/160 reads (16%) | called by mutect2, varscan2
- CDK5RAP3 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 138/1092 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CDR2L | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 184/1378 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD3 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 112/945 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.388); called by muse, varscan2
- CHD7 | c.6847A>G p.T2283A | Missense Mutation (SNP) | VAF 107/807 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CLC | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 95/982 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CLUH | c.2653G>A p.A885T (on ENST00000435359; = p.A924T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/1131 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- COL5A1 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 168/1172 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, varscan2
- COL5A3 | c.1750G>T p.G584* | Nonsense Mutation (SNP) | VAF 139/959 reads (14%) | called by muse, mutect2, varscan2
- CORO6 | c.116_118del p.F39del | In Frame Del (DEL) | VAF 147/1386 reads (11%) | called by mutect2, pindel, varscan2
- CP | c.278del p.L93* | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by pindel, varscan2
- CPSF3 | c.1799del p.K600Rfs*6 | Frame Shift Del (DEL) | VAF 26/215 reads (12%) | called by mutect2, pindel, varscan2
- CYP4F22 | c.1073A>C p.Q358P | Missense Mutation (SNP) | VAF 118/1282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DACT2 | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 213/863 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- DDX56 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 111/844 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DENND1C | c.1436del p.G479Afs*3 | Frame Shift Del (DEL) | VAF 128/1192 reads (11%) | called by pindel, varscan2
- DHX34 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 176/1335 reads (13%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DHX38 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 70/552 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); called by mutect2, varscan2
- DLX4 | c.299G>A p.R100Q (on ENST00000240306 / NM_138281.3; = p.R28Q on NM_001934.3) | Missense Mutation (SNP) | VAF 225/1739 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH1 | c.685del p.Q229Kfs*17 | Frame Shift Del (DEL) | VAF 178/1456 reads (12%) | called by pindel, varscan2
- DOCK3 | c.3967A>G p.S1323G | Missense Mutation (SNP) | VAF 108/699 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DOCK6 | c.451del p.R151Afs*44 | Frame Shift Del (DEL) | VAF 158/1202 reads (13%) | called by pindel, varscan2
- DTX4 | c.279G>T p.W93C | Missense Mutation (SNP) | VAF 181/1425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DUS1L | c.939G>T p.Q313H | Missense Mutation (SNP) | VAF 96/871 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- EFCAB8 | c.1469T>C p.L490S | Missense Mutation (SNP) | VAF 116/994 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- EHBP1L1 | c.2861C>G p.A954G | Missense Mutation (SNP) | VAF 166/1294 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- ENC1 | c.1496del p.G499Vfs*26 | Frame Shift Del (DEL) | VAF 98/864 reads (11%) | called by mutect2, varscan2
- EPHA6 | c.680A>C p.D227A | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- EPHA8 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC2 | c.949+1G>A p.X317_splice | Splice Site (SNP) | VAF 132/1071 reads (12%) | called by muse, mutect2, varscan2
- ERI3 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 133/1007 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERMARD | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM71A | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 112/954 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- FANCE | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 190/1239 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBN3 | c.6019C>G p.H2007D | Missense Mutation (SNP) | VAF 36/969 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.398); called by muse, mutect2
- FBXO7 | c.524_526del p.V175del | In Frame Del (DEL) | VAF 104/898 reads (12%) | called by mutect2, pindel, varscan2
- FEM1A | c.1536del p.S513Afs*5 | Frame Shift Del (DEL) | VAF 142/1094 reads (13%) | called by mutect2, varscan2
- FKRP | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 61/1666 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.057); called by muse, mutect2
- FLNA | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 20/637 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- FNDC7 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 155/1330 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOXD4L1 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 320/2046 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXG1 | c.475dup p.A159Gfs*296 | Frame Shift Ins (INS) | VAF 60/630 reads (10%) | called by mutect2, pindel
- FURIN | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 199/1652 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GABRG2 | c.377T>A p.L126* | Nonsense Mutation (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- GALNT9 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 172/1328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GARRE1 | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 104/1006 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- GDPD3 | c.953_955del p.S318del | In Frame Del (DEL) | VAF 98/733 reads (13%) | called by pindel, varscan2
- GLI3 | c.1075A>G p.M359V | Missense Mutation (SNP) | VAF 144/1033 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAL | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 74/582 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GOLGA6L9 | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 70/534 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); called by mutect2, varscan2
- GPN1 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 63/581 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR135 | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 185/1443 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR3 | c.767T>A p.F256Y | Missense Mutation (SNP) | VAF 70/1590 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- GPR6 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 185/1267 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GRIK3 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 151/1382 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- GRK3 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 75/500 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GRM6 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 137/1131 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- GTF3C1 | c.4225_4227dup p.K1409dup | In Frame Ins (INS) | VAF 46/421 reads (11%) | called by mutect2, pindel
- GUCY2D | c.2568G>A p.M856I | Missense Mutation (SNP) | VAF 58/509 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- HMBOX1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 41/664 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- HMGXB4 | c.514dup p.M172Nfs*17 | Frame Shift Ins (INS) | VAF 89/815 reads (11%) | called by mutect2, varscan2
- HSBP1L1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 41/460 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ICAM3 | c.631del p.R211Afs*10 | Frame Shift Del (DEL) | VAF 143/968 reads (15%) | called by mutect2, pindel, varscan2
- IFT88 | c.447A>T p.Q149H (on ENST00000319980 / NM_001318493.2; = p.Q140H on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- IGDCC4 | c.2925_2926del p.A976Wfs*41 | Frame Shift Del (DEL) | VAF 138/1330 reads (10%) | called by pindel, varscan2
- IGLV3-10 | c.147del p.K49Nfs*43 | Frame Shift Del (DEL) | VAF 83/826 reads (10%) | called by mutect2, pindel, varscan2
- IQSEC2 | c.2962del p.Q988Rfs*3 (on ENST00000642864 / NM_001111125.3; = p.Q783Rfs*3 on NM_015075.2) | Frame Shift Del (DEL) | VAF 209/813 reads (26%) | called by mutect2, pindel, varscan2
- IRS2 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 31/1275 reads (2%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); called by muse, mutect2
- ITGB2 | c.1321G>A p.A441T (on ENST00000302347; = p.A417T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/894 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2
- KANSL2 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 92/825 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- KDM6A | c.1901del p.N634Tfs*57 | Frame Shift Del (DEL) | VAF 111/498 reads (22%) | called by mutect2, pindel, varscan2
- KIAA1522 | c.15del p.A8Pfs*82 | Frame Shift Del (DEL) | VAF 56/429 reads (13%) | called by mutect2, pindel, varscan2
- KIAA2012 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 178/1378 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- KIF7 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 179/1261 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- KMT2B | c.7176dup p.E2393* | Frame Shift Ins (INS) | VAF 138/959 reads (14%) | called by mutect2, pindel, varscan2
- KRTAP5-1 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 161/1223 reads (13%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LGR4 | c.1841C>T p.T614I | Missense Mutation (SNP) | VAF 82/854 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- MACF1 | c.19762C>T p.L6588F (on ENST00000372915; = p.L4633F on NM_012090.5) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- MCIDAS | c.200A>C p.E67A | Missense Mutation (SNP) | VAF 115/1046 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCM5 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 142/1177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MEI1 | c.175-1G>A p.X59_splice | Splice Site (SNP) | VAF 64/431 reads (15%) | called by muse, mutect2, varscan2
- MROH1 | c.2719C>A p.L907I | Missense Mutation (SNP) | VAF 63/1492 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2
- MTMR6 | c.1710del p.F570Lfs*9 | Frame Shift Del (DEL) | VAF 77/404 reads (19%) | called by mutect2, pindel, varscan2
- MYH4 | c.2450G>A p.C817Y | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MYO15B | c.3428C>A p.P1143Q | Missense Mutation (SNP) | VAF 142/1071 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NCK1 | c.635A>G p.E212G | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- NHLH2 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 124/1682 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2
- NKX2-5 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 240/1676 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NOS1 | c.520dup p.H174Pfs*31 | Frame Shift Ins (INS) | VAF 205/1780 reads (12%) | called by mutect2, pindel, varscan2
- NPAS2 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 104/903 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- NPLOC4 | c.1300A>G p.N434D | Missense Mutation (SNP) | VAF 132/945 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NR2F6 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 72/1852 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.138); called by muse, mutect2
- NUP98 | c.3032A>G p.Q1011R (on ENST00000359171 / NM_001365126.1; = p.Q994R on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/660 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NYNRIN | c.4834G>T p.A1612S | Missense Mutation (SNP) | VAF 190/1248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ONECUT1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 129/940 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR56A3 | c.841A>G p.N281D | Missense Mutation (SNP) | VAF 117/1129 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR7D2 | c.533del p.F178Sfs*4 | Frame Shift Del (DEL) | VAF 100/942 reads (11%) | called by mutect2, pindel, varscan2
- PACS1 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 198/1436 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, varscan2
- PAPLN | c.1147C>A p.Q383K (on ENST00000554301; = p.Q356K on NM_173462.4) | Missense Mutation (SNP) | VAF 144/1107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH7 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 195/1405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA11 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 147/1248 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PCDHB10 | c.892del p.S298Lfs*14 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | called by mutect2, pindel
- PCDHB2 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDHGA11 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 154/1314 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PDE5A | c.1414A>G p.N472D | Missense Mutation (SNP) | VAF 37/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDZK1 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 81/512 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PKD1 | c.12263_12264del p.V4088Gfs*68 (on ENST00000262304 / NM_001009944.3; = p.V4087Gfs*68 on NM_000296.4) | Frame Shift Del (DEL) | VAF 227/1814 reads (13%) | called by pindel, varscan2
- PKD1 | c.2891T>C p.V964A | Missense Mutation (SNP) | VAF 71/667 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLD1 | c.104T>C p.F35S | Missense Mutation (SNP) | VAF 123/948 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PLEKHG2 | c.139dup p.R47Pfs*15 | Frame Shift Ins (INS) | VAF 163/1362 reads (12%) | called by mutect2, pindel, varscan2
- POLR2M | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 220/1677 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- POMGNT2 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 170/1355 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PON1 | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- POR | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 228/1927 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2
- POU4F2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 318/2055 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.939); called by muse, mutect2
- PPT1 | c.394A>G p.M132V (on ENST00000433473; = p.M133V on NM_000310.4) | Missense Mutation (SNP) | VAF 104/841 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PRSS55 | c.863dup p.L288Ffs*70 | Frame Shift Ins (INS) | VAF 110/1164 reads (9%) | called by mutect2, pindel
- PTGS1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 200/1506 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2
- PTH1R | c.1362del p.F454Lfs*52 | Frame Shift Del (DEL) | VAF 109/828 reads (13%) | called by mutect2, pindel, varscan2
- PTPRM | c.3892T>C p.Y1298H | Missense Mutation (SNP) | VAF 32/793 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PYROXD2 | c.1443_1446del p.D481Efs*81 | Frame Shift Del (DEL) | VAF 52/528 reads (10%) | called by pindel, varscan2
- RADIL | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 183/1825 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- RBM12 | c.1878_1879del p.E626Dfs*2 | Frame Shift Del (DEL) | VAF 56/534 reads (10%) | called by pindel, varscan2
- RELN | c.2672A>G p.Q891R | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RNF111 | c.2318del p.P773Hfs*44 | Frame Shift Del (DEL) | VAF 158/1068 reads (15%) | called by mutect2, pindel, varscan2
- RNF126 | c.547dup p.A183Gfs*16 | Frame Shift Ins (INS) | VAF 122/960 reads (13%) | called by mutect2, pindel, varscan2
- RNFT1 | c.460del p.S154Vfs*6 | Frame Shift Del (DEL) | VAF 70/565 reads (12%) | called by mutect2, pindel, varscan2
- RPL3L | c.206A>T p.K69I | Missense Mutation (SNP) | VAF 30/1018 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RPLP1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 86/847 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SCN2A | c.5104A>G p.N1702D | Missense Mutation (SNP) | VAF 86/1328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- SEMA5A | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 50/856 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SF1 | c.1717del p.V573Sfs*23 | Frame Shift Del (DEL) | VAF 130/1170 reads (11%) | called by pindel, varscan2
- SHANK1 | c.5015A>T p.D1672V | Missense Mutation (SNP) | VAF 199/1674 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SHROOM2 | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 203/905 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIN3A | c.737del p.P246Hfs*41 | Frame Shift Del (DEL) | VAF 170/1253 reads (14%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.171_172dup p.R58Pfs*9 | Frame Shift Ins (INS) | VAF 120/1134 reads (11%) | called by mutect2, varscan2
- SLC15A3 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 181/1098 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A39 | c.431C>T p.A144V (on ENST00000377095 / NM_001143780.3; = p.A136V on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/843 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SLC4A2 | c.3686A>C p.E1229A | Missense Mutation (SNP) | VAF 159/1246 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC6A5 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 295/1875 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SMARCA2 | c.3508C>T p.R1170W | Missense Mutation (SNP) | VAF 105/923 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SMIM10L2B | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 120/464 reads (26%) | SIFT deleterious (0); called by muse, varscan2
- SON | c.2060T>C p.V687A | Missense Mutation (SNP) | VAF 45/1194 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2
- SOX1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 50/1550 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- SRCIN1 | c.3003del p.K1002Rfs*23 (on ENST00000621492; = p.K968Rfs*23 on NM_025248.3) | Frame Shift Del (DEL) | VAF 122/736 reads (17%) | called by mutect2, varscan2
- STARD7 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SUGP2 | c.2452T>G p.F818V | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNRG | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 156/1031 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAAR5 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 142/916 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF3 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 112/906 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by mutect2, varscan2
- TBC1D1 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 129/1274 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TBC1D5 | c.2252del p.P751Qfs*12 | Frame Shift Del (DEL) | VAF 171/1716 reads (10%) | called by mutect2, pindel
- TBL3 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 152/1174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TBL3 | c.1669A>G p.K557E | Missense Mutation (SNP) | VAF 130/952 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- TPGS1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 148/944 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TPX2 | c.1048_1050del p.D350del | In Frame Del (DEL) | VAF 6/49 reads (12%) | called by pindel, varscan2
- TRAPPC10 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 183/1114 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPM6 | c.104del p.N35Ifs*15 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- TRPV1 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 97/1058 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- TTN | c.71881C>T p.P23961S (on ENST00000591111; = p.P16537S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/350 reads (5%) | PolyPhen possibly damaging (0.897); called by muse, mutect2
- TTPA | c.215del p.N72Tfs*12 | Frame Shift Del (DEL) | VAF 16/173 reads (9%) | called by mutect2, pindel
- TUBA1B | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 174/1430 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TUBGCP3 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 318/984 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.411); called by muse, varscan2
- UBXN8 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 98/702 reads (14%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ULK1 | c.1857del p.I620Sfs*27 | Frame Shift Del (DEL) | VAF 235/1791 reads (13%) | called by mutect2, pindel, varscan2
- USP46 | c.1084T>C p.Y362H | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, varscan2
- UTF1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 182/1387 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- VKORC1L1 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 114/836 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- VPS37C | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 217/1618 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WDR5 | c.425A>T p.N142I | Missense Mutation (SNP) | VAF 66/800 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- WDR64 | c.1837T>C p.S613P | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- WDR90 | c.4997A>C p.Q1666P | Missense Mutation (SNP) | VAF 84/625 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- WNT10A | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 160/1071 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, varscan2
- ZFR2 | c.2467A>G p.S823G | Missense Mutation (SNP) | VAF 211/1527 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF638 | c.3459del p.A1154Qfs*28 | Frame Shift Del (DEL) | VAF 32/308 reads (10%) | called by mutect2, pindel, varscan2
- ZNRF4 | c.378del p.E127Rfs*7 | Frame Shift Del (DEL) | VAF 168/1544 reads (11%) | called by mutect2, varscan2
- ZSWIM2 | c.53G>T p.R18M | Missense Mutation (SNP) | VAF 110/997 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ABCA9 | c.4188C>T p.D1396= | Silent (SNP) | VAF 121/883 reads (14%) | catalogued as rs552343216, COSV60619980; called by muse, mutect2, varscan2
- ABCG1 | c.1299C>T p.I433= | Silent (SNP) | VAF 137/1212 reads (11%) | catalogued as rs754413272, COSV59203009; called by muse, varscan2
- ABHD16B | c.681C>T p.V227= | Silent (SNP) | VAF 201/1428 reads (14%) | catalogued as rs752217260, COSV53861529, COSV53863554; called by muse, mutect2, varscan2
- ACVR1B | c.828A>G p.T276= | Silent (SNP) | VAF 35/875 reads (4%) | called by muse, mutect2
- ADAMTSL4 | c.1650C>T p.A550= | Silent (SNP) | VAF 201/1505 reads (13%) | catalogued as rs144197372; called by muse, mutect2, varscan2
- ADCY4 | c.91C>T p.L31= | Silent (SNP) | VAF 198/1373 reads (14%) | catalogued as COSV99353481; called by muse, varscan2
- ADCY8 | c.2277C>A p.T759= | Silent (SNP) | VAF 131/1084 reads (12%) | called by muse, mutect2, varscan2
- ADRA1A | c.1134C>T p.P378= | Silent (SNP) | VAF 162/1436 reads (11%) | catalogued as rs750303232, COSV52375166; called by muse, mutect2, varscan2
- AJM1 | c.2664C>T p.G888= | Silent (SNP) | VAF 139/1087 reads (13%) | catalogued as COSV56035068; called by muse, varscan2
- ANKFY1 | c.2391C>T p.N797= (on ENST00000341657 / NM_001330063.2; = p.N798= on NM_016376.5) | Silent (SNP) | VAF 137/1028 reads (13%) | catalogued as rs375613181; called by muse, mutect2, varscan2
- ANKRD26 | c.936C>T p.S312= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs770877386, COSV101066674; called by muse, mutect2, varscan2
- ARFGAP1 | c.567G>A p.T189= | Silent (SNP) | VAF 143/1156 reads (12%) | catalogued as rs755280290, COSV100796606; called by muse, mutect2, varscan2
- ARHGAP15 | c.909A>G p.E303= | Silent (SNP) | VAF 17/466 reads (4%) | called by muse, mutect2
- ARHGAP22 | c.1245G>A p.R415= | Silent (SNP) | VAF 230/1803 reads (13%) | called by muse, mutect2, varscan2
- ARL4C | c.477G>A p.P159= | Silent (SNP) | VAF 168/1235 reads (14%) | catalogued as rs372804936; called by muse, mutect2, varscan2
- B3GNT2 | c.492C>A p.S164= | Silent (SNP) | VAF 177/1288 reads (14%) | called by muse, mutect2, varscan2
- BCL11A | c.2007C>T p.P669= (on ENST00000335712 / NM_001365609.1; = p.P703= on NM_018014.4) | Silent (SNP) | VAF 206/1665 reads (12%) | catalogued as rs777484449, COSV59636109; called by muse, mutect2, varscan2
- BHLHE40 | c.75A>G p.L25= | Silent (SNP) | VAF 168/1156 reads (15%) | called by muse, mutect2, varscan2
- C16orf95 | c.468G>A p.S156= (on ENST00000253461 / NM_001195125.2; = p.G218S on NM_001195124.3) | Silent (SNP) | VAF 212/1480 reads (14%) | catalogued as rs1391481780; called by muse, mutect2, varscan2
- C1QTNF12 | c.453C>T p.G151= | Silent (SNP) | VAF 199/1384 reads (14%) | catalogued as rs753067712; called by muse, mutect2, varscan2
- C5 | c.1980T>C p.D660= | Silent (SNP) | VAF 53/484 reads (11%) | called by muse, mutect2, varscan2
- CASP5 | c.114C>T p.N38= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs747142816; called by mutect2, varscan2
- CD34 | c.21G>A p.A7= | Silent (SNP) | VAF 169/1036 reads (16%) | catalogued as COSV100178349; called by muse, varscan2
- CDK18 | c.1116G>T p.P372= (on ENST00000506784 / NM_212503.3; = p.P342= on NM_002596.4) | Silent (SNP) | VAF 153/1081 reads (14%) | called by muse, mutect2, varscan2
- CHAT | c.414G>A p.P138= | Silent (SNP) | VAF 111/1011 reads (11%) | catalogued as rs199675090, COSV60319880; called by muse, mutect2, varscan2
- CHD6 | c.8136C>T p.N2712= | Silent (SNP) | VAF 104/828 reads (13%) | catalogued as rs148480354; called by muse, varscan2
- CHMP1A | c.84G>A p.A28= | Silent (SNP) | VAF 220/1489 reads (15%) | catalogued as rs376691010; called by muse, mutect2, varscan2
- CLCNKA | c.1284C>T p.P428= | Silent (SNP) | VAF 77/1634 reads (5%) | called by muse, mutect2
- CLEC7A | c.33T>C p.D11= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- COL11A1 | c.2403T>C p.V801= | Silent (SNP) | VAF 99/810 reads (12%) | called by muse, mutect2, varscan2
- COL4A3 | c.2460A>G p.P820= | Silent (SNP) | VAF 150/1536 reads (10%) | called by muse, mutect2
- CPPED1 | c.711C>T p.H237= | Silent (SNP) | VAF 119/744 reads (16%) | catalogued as rs764518637, COSV99902675; called by muse, mutect2, varscan2
- CTNND2 | c.1443C>T p.A481= | Silent (SNP) | VAF 182/1728 reads (11%) | catalogued as rs140702980; called by muse, mutect2, varscan2
- CYP26A1 | c.225C>T p.Y75= | Silent (SNP) | VAF 133/895 reads (15%) | catalogued as rs1211322346, COSV56417156; called by muse, mutect2, varscan2
- DACT3 | c.1827C>T p.H609= | Silent (SNP) | VAF 145/1118 reads (13%) | called by muse, mutect2, varscan2
- DGKZ | c.2322C>T p.R774= (on ENST00000454345 / NM_001105540.2; = p.R586= on NM_003646.4) | Silent (SNP) | VAF 154/1685 reads (9%) | catalogued as rs935761946; called by muse, mutect2
- DOHH | c.513G>A p.P171= | Silent (SNP) | VAF 204/1485 reads (14%) | catalogued as rs775656921; called by muse, mutect2, varscan2
- EMC10 | c.597G>A p.A199= | Silent (SNP) | VAF 141/1215 reads (12%) | catalogued as rs143690196; called by muse, mutect2, varscan2
- FAM163B | c.324G>A p.P108= | Silent (SNP) | VAF 204/1673 reads (12%) | catalogued as rs577261032; called by muse, mutect2, varscan2
- FARP1 | c.1722C>T p.D574= | Silent (SNP) | VAF 98/905 reads (11%) | catalogued as rs770039478; called by muse, mutect2, varscan2
- FEM1A | c.1447A>C p.R483= | Silent (SNP) | VAF 167/1270 reads (13%) | called by muse, mutect2, varscan2
- FLT4 | c.3270G>A p.V1090= | Silent (SNP) | VAF 206/1710 reads (12%) | called by muse, mutect2, varscan2
- FSCN1 | c.1158C>T p.I386= | Silent (SNP) | VAF 122/1028 reads (12%) | catalogued as rs749144857; called by muse, varscan2
- GOLGA3 | c.3678G>A p.K1226= | Silent (SNP) | VAF 62/1311 reads (5%) | catalogued as rs1403423557; called by muse, mutect2
- GOLGA3 | c.2352G>A p.A784= | Silent (SNP) | VAF 180/1361 reads (13%) | catalogued as rs773796316; called by muse, mutect2, varscan2
- GPR88 | c.1059C>T p.G353= | Silent (SNP) | VAF 194/1251 reads (16%) | called by muse, varscan2
- HCN2 | c.1227G>A p.S409= | Silent (SNP) | VAF 64/552 reads (12%) | catalogued as rs114340240; called by muse, mutect2, varscan2
- HDAC4 | c.555G>A p.A185= | Silent (SNP) | VAF 130/1111 reads (12%) | catalogued as rs769558200; called by muse, mutect2, varscan2
- HDAC4 | c.318G>A p.A106= | Silent (SNP) | VAF 87/741 reads (12%) | catalogued as rs972453387; called by muse, mutect2, varscan2
- HDAC5 | c.579G>A p.S193= | Silent (SNP) | VAF 88/856 reads (10%) | catalogued as rs1481818318; called by muse, mutect2, varscan2
- HNRNPL | c.135C>T p.G45= | Silent (SNP) | VAF 195/1446 reads (13%) | catalogued as rs779734803; called by muse, varscan2
- HSD17B4 | c.84A>G p.L28= (on ENST00000414835 / NM_001199291.3; = p.Y25C on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/83 reads (30%) | called by mutect2, varscan2
- HTRA3 | c.162C>T p.C54= | Silent (SNP) | VAF 197/1408 reads (14%) | called by muse, mutect2, varscan2
- IMPDH1 | c.1170C>T p.A390= (on ENST00000470772 / NM_001142573.2; = p.A476= on NM_000883.4) | Silent (SNP) | VAF 99/833 reads (12%) | catalogued as rs199527034, COSV58317872; called by muse, mutect2, varscan2
- INSRR | c.2010G>A p.P670= | Silent (SNP) | VAF 190/1554 reads (12%) | catalogued as rs1232395470, COSV63876548; called by muse, mutect2, varscan2
- IQSEC1 | c.897G>A p.S299= | Silent (SNP) | VAF 173/1372 reads (13%) | catalogued as rs772363453, COSV56223120; called by muse, varscan2
- IRS2 | c.2451C>T p.G817= | Silent (SNP) | VAF 415/1527 reads (27%) | catalogued as rs769413761, COSV65480968; called by mutect2, varscan2
- ISLR2 | c.1446C>T p.H482= | Silent (SNP) | VAF 189/1321 reads (14%) | catalogued as rs756198114; called by muse, mutect2, varscan2
- KCNH2 | c.843C>T p.R281= | Silent (SNP) | VAF 174/1387 reads (13%) | called by muse, varscan2
- KCNJ16 | c.42C>T p.D14= | Silent (SNP) | VAF 96/1140 reads (8%) | catalogued as rs148762846, COSV52253062; called by muse, mutect2
- KCTD19 | c.516G>A p.V172= | Silent (SNP) | VAF 157/1279 reads (12%) | catalogued as rs752988948; called by muse, mutect2, varscan2
- KIAA0100 | c.4689T>C p.I1563= | Silent (SNP) | VAF 198/1237 reads (16%) | called by muse, mutect2, varscan2
- KIF17 | c.894C>T p.D298= | Silent (SNP) | VAF 190/1265 reads (15%) | called by muse, mutect2, varscan2
- KIF4B | c.2794C>T p.L932= | Silent (SNP) | VAF 155/1250 reads (12%) | catalogued as rs747961785; called by muse, mutect2, varscan2
- KLHDC9 | c.246C>T p.H82= | Silent (SNP) | VAF 224/1591 reads (14%) | catalogued as rs1442525657; called by muse, mutect2, varscan2
- KLHL36 | c.1443G>A p.T481= | Silent (SNP) | VAF 177/1415 reads (13%) | catalogued as rs761105656; called by muse, mutect2, varscan2
- KLK4 | c.57C>T p.V19= | Silent (SNP) | VAF 114/1027 reads (11%) | catalogued as COSV60676153; called by muse, mutect2, varscan2
- KMT2B | c.5391T>G p.A1797= | Silent (SNP) | VAF 129/1055 reads (12%) | catalogued as COSV99718704; called by muse, mutect2, varscan2
- KRTAP10-5 | c.339G>A p.Q113= | Silent (SNP) | VAF 209/1894 reads (11%) | catalogued as rs879963618; called by muse, mutect2, varscan2
- LAMA1 | c.7497G>A p.L2499= | Silent (SNP) | VAF 120/1090 reads (11%) | catalogued as COSV67544791; called by muse, mutect2, varscan2
- LARGE1 | c.543C>A p.I181= | Silent (SNP) | VAF 136/1244 reads (11%) | catalogued as COSV61672316; called by muse, mutect2, varscan2
- LEFTY2 | c.480C>A p.T160= | Silent (SNP) | VAF 118/946 reads (12%) | called by muse, varscan2
- LIM2 | c.477C>T p.C159= (on ENST00000596399 / NM_001161748.2; = p.C201= on NM_030657.4) | Silent (SNP) | VAF 114/1132 reads (10%) | catalogued as rs200867286, COSV55742697; called by muse, mutect2
- LPAR5 | c.741C>T p.F247= | Silent (SNP) | VAF 194/1319 reads (15%) | catalogued as rs550346191, COSV100321019; called by muse, mutect2, varscan2
- M1AP | c.834C>T p.D278= | Silent (SNP) | VAF 133/1667 reads (8%) | catalogued as rs745433133, COSV51849861; called by muse, mutect2
- MATK | c.603C>T p.G201= (on ENST00000310132 / NM_139355.3; = p.G202= on NM_002378.4) | Silent (SNP) | VAF 76/1448 reads (5%) | catalogued as rs758490558, COSV59556253; called by muse, mutect2
- MEGF6 | c.1197C>T p.A399= | Silent (SNP) | VAF 115/1130 reads (10%) | catalogued as rs374339674; called by muse, mutect2, varscan2
- MTSS2 | c.1845C>T p.C615= | Silent (SNP) | VAF 225/1637 reads (14%) | catalogued as rs767275878; called by muse, mutect2, varscan2
- MYLK | c.4497A>T p.S1499= | Silent (SNP) | VAF 92/718 reads (13%) | called by muse, mutect2, varscan2
- MYO16 | c.4770C>T p.C1590= | Silent (SNP) | VAF 458/1688 reads (27%) | catalogued as COSV62750694; called by muse, mutect2, varscan2
- NDN | c.150C>T p.A50= | Silent (SNP) | VAF 202/1529 reads (13%) | catalogued as rs1412745565; called by muse, mutect2, varscan2
- NDRG4 | c.21G>A p.R7= | Silent (SNP) | VAF 162/1045 reads (16%) | called by muse, mutect2, varscan2
- NKX2-4 | c.270C>G p.A90= | Silent (SNP) | VAF 138/828 reads (17%) | called by mutect2, varscan2
- NOL4L | c.357C>T p.R119= | Silent (SNP) | VAF 170/1246 reads (14%) | catalogued as rs777888640; called by muse, mutect2, varscan2
- NPBWR1 | c.774G>A p.A258= | Silent (SNP) | VAF 161/1178 reads (14%) | catalogued as rs1163156562, COSV58695549; called by muse, mutect2, varscan2
- NRXN2 | c.4668G>A p.P1556= | Silent (SNP) | VAF 207/1869 reads (11%) | catalogued as rs758220644; called by muse, mutect2, varscan2
- NUAK1 | c.1221C>T p.S407= | Silent (SNP) | VAF 138/1428 reads (10%) | catalogued as rs368677538; called by muse, mutect2
- NUTM1 | c.3270A>G p.S1090= | Silent (SNP) | VAF 112/1334 reads (8%) | called by muse, mutect2
- NYAP2 | c.798C>T p.A266= | Silent (SNP) | VAF 181/1460 reads (12%) | catalogued as rs779640204, COSV56001563; called by muse, mutect2, varscan2
- OBSCN | c.8166C>T p.S2722= | Silent (SNP) | VAF 182/1086 reads (17%) | catalogued as rs376333828; called by muse, mutect2, varscan2
- OLFM2 | c.915G>T p.P305= | Silent (SNP) | VAF 166/1432 reads (12%) | called by muse, mutect2, varscan2
- P4HTM | c.28C>A p.R10= | Silent (SNP) | VAF 80/990 reads (8%) | called by muse, mutect2
- PAN2 | c.1056C>T p.G352= | Silent (SNP) | VAF 137/1272 reads (11%) | called by muse, mutect2, varscan2
- PBX4 | c.945G>A p.P315= | Silent (SNP) | VAF 144/1088 reads (13%) | catalogued as rs372278117; called by muse, varscan2
- PCDH12 | c.780T>C p.G260= | Silent (SNP) | VAF 155/1254 reads (12%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1689G>A p.A563= | Silent (SNP) | VAF 219/1272 reads (17%) | catalogued as rs782448076, COSV100249405; called by muse, mutect2, varscan2
- PGR | c.1047G>A p.S349= | Silent (SNP) | VAF 125/1042 reads (12%) | catalogued as rs778224917; called by muse, mutect2, varscan2
- PIEZO1 | c.5958G>A p.S1986= | Silent (SNP) | VAF 97/767 reads (13%) | catalogued as rs927362544, COSV99965836; called by muse, mutect2, varscan2
- PLXNA1 | c.5670C>T p.D1890= | Silent (SNP) | VAF 147/1215 reads (12%) | called by muse, mutect2, varscan2
- PNMA8A | c.663G>A p.T221= | Silent (SNP) | VAF 177/1431 reads (12%) | catalogued as rs369554909, COSV58137212; called by muse, mutect2, varscan2
- PNPLA1 | c.648C>T p.C216= (on ENST00000394571 / NM_001374623.1; = p.C121= on NM_173676.2) | Silent (SNP) | VAF 112/972 reads (12%) | called by muse, mutect2, varscan2
- POM121C | c.3201G>A p.S1067= (on ENST00000607367; = p.S825= on NM_001099415.3) | Silent (SNP) | VAF 128/1366 reads (9%) | catalogued as rs587682396; called by muse, varscan2
- POM121L2 | c.1113C>T p.N371= | Silent (SNP) | VAF 174/898 reads (19%) | called by muse, mutect2, varscan2
- POTEJ | c.273C>T p.F91= | Silent (SNP) | VAF 147/1931 reads (8%) | called by muse, mutect2
- POU4F1 | c.1107C>T p.S369= | Silent (SNP) | VAF 523/1710 reads (31%) | called by muse, mutect2, varscan2
- PRAM1 | c.1704G>A p.K568= | Silent (SNP) | VAF 143/1135 reads (13%) | catalogued as rs977030418; called by muse, mutect2, varscan2
- PROC | c.1233C>T p.H411= | Silent (SNP) | VAF 181/1565 reads (12%) | catalogued as rs777430545, COSV52165231; called by muse, mutect2, varscan2
- PRSS56 | c.1176G>A p.R392= | Silent (SNP) | VAF 120/836 reads (14%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2838G>A p.P946= | Silent (SNP) | VAF 152/1248 reads (12%) | catalogued as rs138464557; called by muse, varscan2
- RAP1GAP | c.741C>T p.H247= | Silent (SNP) | VAF 60/1178 reads (5%) | catalogued as rs750479184; called by muse, mutect2
- RFC4 | c.1056T>C p.C352= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs113707925, COSV56217333; called by muse, mutect2, varscan2
- RFX8 | c.195C>T p.Y65= | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- ROBO2 | c.186T>C p.I62= | Silent (SNP) | VAF 164/1384 reads (12%) | called by muse, mutect2, varscan2
- RSU1 | c.73C>A p.R25= | Silent (SNP) | VAF 82/826 reads (10%) | called by muse, mutect2
- SCARF2 | c.2460G>A p.A820= | Silent (SNP) | VAF 241/1618 reads (15%) | catalogued as COSV104383365; called by muse, mutect2, varscan2
- SCRIB | c.3996G>A p.P1332= | Silent (SNP) | VAF 188/1385 reads (14%) | catalogued as rs1460616299; called by muse, mutect2, varscan2
- SCYL1 | c.2370C>T p.R790= | Silent (SNP) | VAF 145/1259 reads (12%) | catalogued as rs564277938; called by muse, mutect2, varscan2
- SETD1A | c.2670G>A p.L890= | Silent (SNP) | VAF 79/767 reads (10%) | called by mutect2, varscan2
- SFMBT2 | c.2247G>A p.S749= | Silent (SNP) | VAF 209/1752 reads (12%) | catalogued as rs768769212, COSV62814400, COSV62817315; called by muse, mutect2, varscan2
- SFRP1 | c.364C>T p.L122= | Silent (SNP) | VAF 213/1358 reads (16%) | catalogued as rs1192144648; called by muse, mutect2, varscan2
- SLC38A7 | c.774C>T p.H258= | Silent (SNP) | VAF 96/824 reads (12%) | catalogued as rs1278238649; called by muse, varscan2
- SLC45A2 | c.186C>T p.S62= | Silent (SNP) | VAF 143/1205 reads (12%) | catalogued as COSV56869850; called by muse, mutect2, varscan2
- SOGA3 | c.339C>T p.A113= | Silent (SNP) | VAF 188/1312 reads (14%) | catalogued as rs529622383; called by muse, mutect2, varscan2
- SP110 | c.618G>A p.A206= | Silent (SNP) | VAF 100/1060 reads (9%) | catalogued as rs372578277; ClinVar: uncertain significance; called by muse, mutect2
- ST3GAL3 | c.189C>T p.S63= (on ENST00000361392 / NM_174964.4; = p.S48= on NM_006279.5) | Silent (SNP) | VAF 34/440 reads (8%) | catalogued as rs756428954; called by muse, mutect2
- SYNE3 | c.2511C>T p.D837= | Silent (SNP) | VAF 96/860 reads (11%) | called by muse, mutect2, varscan2
- TBC1D22B | c.1458C>T p.L486= | Silent (SNP) | VAF 117/837 reads (14%) | catalogued as rs185992956; called by muse, mutect2, varscan2
- TCP11L1 | c.312A>G p.V104= | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- TERT | c.501C>A p.A167= | Silent (SNP) | VAF 186/1602 reads (12%) | called by muse, mutect2, varscan2
- TERT | c.112C>T p.L38= | Silent (SNP) | VAF 255/1615 reads (16%) | called by muse, mutect2, varscan2
- THBS1 | c.1482C>A p.G494= | Silent (SNP) | VAF 88/868 reads (10%) | called by muse, mutect2
- TKTL2 | c.27C>T p.D9= | Silent (SNP) | VAF 104/796 reads (13%) | catalogued as rs1052342357; called by muse, mutect2, varscan2
- TMEM119 | c.738C>T p.A246= | Silent (SNP) | VAF 184/1470 reads (13%) | catalogued as rs377507463; called by muse, varscan2
- TMPRSS4 | c.189C>T p.L63= | Silent (SNP) | VAF 147/1283 reads (11%) | catalogued as rs780924915; called by muse, mutect2, varscan2
- TNFRSF19 | c.906C>T p.G302= | Silent (SNP) | VAF 154/1418 reads (11%) | catalogued as rs1337084683, COSV50314718; called by muse, varscan2
- TNS2 | c.1389C>T p.H463= (on ENST00000314250 / NM_170754.4; = p.H473= on NM_015319.2) | Silent (SNP) | VAF 80/665 reads (12%) | catalogued as rs148196451; called by muse, mutect2, varscan2
- TRHDE | c.525C>T p.N175= | Silent (SNP) | VAF 131/1246 reads (11%) | catalogued as rs768032130; called by muse, mutect2, varscan2
- TRIM16L | c.501C>T p.H167= | Silent (SNP) | VAF 114/954 reads (12%) | called by muse, mutect2, varscan2
- TRIM3 | c.1071A>G p.T357= | Silent (SNP) | VAF 240/1694 reads (14%) | called by muse, mutect2, varscan2
- TRMT9B | c.738G>A p.S246= | Silent (SNP) | VAF 37/310 reads (12%) | catalogued as rs372929039; called by muse, mutect2, varscan2
- TRPV1 | c.456T>C p.P152= | Silent (SNP) | VAF 100/717 reads (14%) | called by muse, varscan2
- TTN | c.32832A>G p.V10944= (on ENST00000591111; = p.V10017= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- USP54 | c.1036C>T p.L346= | Silent (SNP) | VAF 142/1066 reads (13%) | catalogued as rs369643280; called by muse, mutect2, varscan2
- VCP | c.1935C>T p.I645= | Silent (SNP) | VAF 141/977 reads (14%) | called by muse, mutect2, varscan2
- VWA5A | c.723C>T p.S241= | Silent (SNP) | VAF 101/1113 reads (9%) | catalogued as rs763418057, COSV100795529, COSV100795717; called by muse, mutect2
- VWA5B2 | c.3273G>A p.S1091= | Silent (SNP) | VAF 199/1488 reads (13%) | catalogued as COSV56612662; called by muse, varscan2
- WDR97 | c.4740G>A p.P1580= | Silent (SNP) | VAF 148/1291 reads (11%) | called by muse, varscan2
- WNK2 | c.1818C>T p.S606= | Silent (SNP) | VAF 91/913 reads (10%) | catalogued as rs748632324; called by muse, mutect2, varscan2
- WNT2B | c.426A>G p.V142= (on ENST00000369684 / NM_024494.3; = p.V123= on NM_004185.4) | Silent (SNP) | VAF 88/732 reads (12%) | catalogued as rs749037667; called by muse, mutect2, varscan2
- ZNF281 | c.1686C>A p.S562= | Silent (SNP) | VAF 56/478 reads (12%) | called by muse, varscan2
- ZNF574 | c.1722C>T p.A574= | Silent (SNP) | VAF 150/1230 reads (12%) | called by muse, mutect2, varscan2
- ZNF615 | c.1761G>A p.Q587= | Silent (SNP) | VAF 83/832 reads (10%) | called by muse, mutect2
- ZNHIT6 | c.958T>C p.L320= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- ZXDC | c.621C>A p.P207= | Silent (SNP) | VAF 170/1264 reads (13%) | called by mutect2, varscan2
- AC063924.1 | chr12:45439843 T>C | 5'Flank (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- AKT2 | c.-180C>T | 5'UTR (SNP) | VAF 187/1349 reads (14%) | called by muse, mutect2, varscan2
- ATP6V0E2 | c.*35A>G | 3'UTR (SNP) | VAF 120/828 reads (14%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967843 ins G | 3'Flank (INS) | VAF 107/1043 reads (10%) | called by mutect2, pindel
- CCNYL2 | chr10:42475880 C>T | 5'Flank (SNP) | VAF 79/716 reads (11%) | called by muse, mutect2, varscan2
- CYP4F3 | c.199-1675C>T | Intron (SNP) | VAF 90/915 reads (10%) | catalogued as rs750005821, COSV55411563; called by muse, mutect2
- DDX41 | c.*284G>A | 3'UTR (SNP) | VAF 71/626 reads (11%) | called by muse, varscan2
- DLX2 | c.585+10G>A | Intron (SNP) | VAF 280/1677 reads (17%) | catalogued as rs1474668871; called by muse, mutect2, varscan2
- FBXW7 | c.502-2351dup | Intron (INS) | VAF 30/290 reads (10%) | called by mutect2, pindel, varscan2
- GAMT | c.570+86C>A | Intron (SNP) | VAF 211/1530 reads (14%) | called by muse, mutect2, varscan2
- GLUL | c.-170G>A | 5'UTR (SNP) | VAF 132/1056 reads (13%) | catalogued as rs1005174632; called by muse, mutect2, varscan2
- IQCA1 | c.11+3599C>T | Intron (SNP) | VAF 125/1053 reads (12%) | catalogued as rs934952696; called by muse, mutect2, varscan2
- KLHL33 | c.-45+105del | Intron (DEL) | VAF 158/1260 reads (13%) | called by mutect2, varscan2
- LEKR1 | c.*1190G>A | 3'UTR (SNP) | VAF 80/584 reads (14%) | catalogued as COSV100739437; called by muse, mutect2, varscan2
- LIMCH1 | c.935+7400T>C | Intron (SNP) | VAF 160/1146 reads (14%) | called by muse, mutect2, varscan2
- LIMCH1 | c.935+7401G>T | Intron (SNP) | VAF 164/1156 reads (14%) | catalogued as COSV100573519; called by muse, mutect2, varscan2
- LRGUK | c.1843+8202A>G | Intron (SNP) | VAF 107/891 reads (12%) | catalogued as rs944451724; called by muse, mutect2, varscan2
- METTL17 | c.1266-25C>T | Intron (SNP) | VAF 177/1298 reads (14%) | called by muse, mutect2, varscan2
- MOGAT3 | c.871+24C>T | Intron (SNP) | VAF 194/1562 reads (12%) | catalogued as rs368812462; called by muse, varscan2
- NACA | c.70+3141T>A | Intron (SNP) | VAF 201/1624 reads (12%) | called by muse, mutect2, varscan2
- NADK | c.393+52del | Intron (DEL) | VAF 75/624 reads (12%) | catalogued as rs746550458; called by mutect2, pindel, varscan2
- PNLDC1 | c.-126G>A | 5'UTR (SNP) | VAF 132/1035 reads (13%) | catalogued as rs915907979; called by muse, varscan2
- PRDM11 | chr11:45227361 C>T | 3'Flank (SNP) | VAF 112/989 reads (11%) | catalogued as rs760617886; called by muse, mutect2, varscan2
- SLC35A3 | c.*211del | 3'UTR (DEL) | VAF 4/23 reads (17%) | called by pindel, varscan2
- SLC9A3 | c.*94C>A | 3'UTR (SNP) | VAF 166/1221 reads (14%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2046A>G | Intron (SNP) | VAF 6/141 reads (4%) | called by muse, mutect2
- TJP1 | c.*1289del | 3'UTR (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- TMEM105 | n.890G>A | RNA (SNP) | VAF 227/1741 reads (13%) | catalogued as rs574731103, COSV59654814; called by muse, mutect2, varscan2
- TMEM155 | c.-362G>A | 5'UTR (SNP) | VAF 159/1126 reads (14%) | called by muse, mutect2, varscan2
- VIPR2 | c.51+402C>T | Intron (SNP) | VAF 114/978 reads (12%) | catalogued as rs775085903; called by muse, mutect2, varscan2
- ZNF175 | c.*1102dup | 3'UTR (INS) | VAF 18/174 reads (10%) | catalogued as rs1284176606; called by mutect2, varscan2
